Somatic mutation profile of tumor specimen TCGA-26-A7UX-01B (aliquot TCGA-26-A7UX-01B-11D-A391-08) from TCGA case TCGA-26-A7UX, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 47.5 years (17,365 days).
Specimen TCGA-26-A7UX-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60b646a7-99fa-448f-8813-b876f9b928bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-26-A7UX-10A (Blood Derived Normal), aliquot TCGA-26-A7UX-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3d17660-244f-49f4-99fb-1510b99cb6b4

The open-access MAF lists 38 somatic variants for this specimen: 30 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 27, Silent 8, Splice Site 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARFGEF3 | c.2057G>A p.R686Q | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs371564929; called by muse, mutect2, varscan2
- ATP10B | c.1297G>A p.D433N | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761267388, COSV58781261; called by muse, mutect2, varscan2
- ATP6V1G3 | c.184-2A>T p.X62_splice | Splice Site (SNP) | VAF 17/30 reads (57%) | catalogued as COSV99810856; called by muse, mutect2, varscan2
- CADPS | c.1405G>A p.V469I | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.972); catalogued as rs200814072, COSV99338116; called by muse, mutect2, varscan2
- CEP290 | c.7300G>A p.E2434K | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100468688; called by muse, mutect2, varscan2
- CFH | c.385T>C p.C129R | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100661434; called by muse, mutect2, varscan2
- CYP2A7 | c.647C>T p.T216M | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.103); catalogued as COSV52500506; called by muse, mutect2, varscan2
- DTX2 | c.61G>A p.V21M | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773085420, COSV100184592; called by muse, mutect2, varscan2
- EMX1 | c.369G>A p.M123I | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.26); PolyPhen benign (0.097); catalogued as rs1284681277, COSV99252492; called by muse, mutect2, varscan2
- FBXL13 | c.778-1G>T p.X260_splice | Splice Site (SNP) | VAF 8/19 reads (42%) | catalogued as COSV99978396; called by muse, mutect2
- FCGBP | c.6824C>T p.P2275L | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1452040648; called by muse, mutect2, varscan2
- FLT1 | c.2648C>G p.T883S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.42); catalogued as COSV99156093; called by muse, mutect2, varscan2
- FNDC1 | c.964A>T p.I322F | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV99795771; called by muse, mutect2, varscan2
- GIGYF1 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs1019609332, COSV99309101; called by muse, varscan2
- GLI3 | c.4736T>C p.M1579T | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV101229857; called by muse, mutect2, varscan2
- GPATCH8 | c.140T>C p.L47S | Missense Mutation (SNP) | VAF 107/211 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100132648; called by muse, mutect2, varscan2
- MAP3K1 | c.1341G>T p.L447F | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101266743; called by muse, mutect2, varscan2
- NISCH | c.2674C>T p.R892C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as rs145350144; called by mutect2, varscan2
- NOL10 | c.1052G>T p.C351F | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100630080; called by muse, mutect2, varscan2
- OR12D3 | c.640C>T p.L214F | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.521); catalogued as rs776423998, COSV101011273; called by muse, mutect2, varscan2
- OR9A4 | c.584C>T p.T195M | Missense Mutation (SNP) | VAF 60/195 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as rs369571264; called by muse, mutect2, varscan2
- OTUD6A | c.116C>T p.T39M | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as rs765873831, COSV57973837; called by muse, varscan2
- PCDHGA4 | c.2256G>T p.K752N | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.076); catalogued as rs1169446996, COSV99537893; called by muse, mutect2, varscan2
- PITPNA | c.328A>G p.K110E | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.71); catalogued as COSV100541478; called by muse, mutect2, varscan2
- TGIF2LX | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 49/64 reads (77%) | SIFT tolerated (0.06); PolyPhen benign (0.184); catalogued as COSV99383336; called by muse, mutect2, varscan2
- TRIML2 | c.285G>T p.Q95H | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58714720; called by muse, mutect2, varscan2
- USP29 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs767708929, COSV54243085; called by muse, mutect2, varscan2
- ZMYND8 | c.2665A>G p.S889G (on ENST00000311275 / NM_001363741.2; = p.S863G on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV99520356; called by muse, mutect2, varscan2
- ZNF341 | c.2261G>A p.R754H (on ENST00000375200 / NM_001282935.1; = p.R747H on NM_032819.4) | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs375592064; called by muse, mutect2, varscan2
- PTEN | c.227_228del p.Y76* | Frame Shift Del (DEL) | VAF 26/37 reads (70%) | called by mutect2, pindel, varscan2
- HTR3D | c.1086G>A p.A362= (on ENST00000382489 / NM_001163646.2; = p.A187= on NM_182537.3) | Silent (SNP) | VAF 24/35 reads (69%) | catalogued as rs368199300; called by muse, mutect2, varscan2
- OR2A7 | c.618G>T p.L206= | Silent (SNP) | VAF 22/154 reads (14%) | catalogued as COSV101512214; called by muse, varscan2
- PPL | c.1194G>A p.P398= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs752842442, COSV100630759; called by muse, mutect2, varscan2
- SLC17A1 | c.819G>A p.T273= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as rs138342129; called by muse, mutect2, varscan2
- TMEM160 | c.252C>T p.I84= | Silent (SNP) | VAF 7/98 reads (7%) | catalogued as rs1254440832, COSV99451353; called by muse, mutect2
- UTP20 | c.2652C>T p.A884= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs758804530, COSV55384135, COSV99881770; called by muse, mutect2, varscan2
- ZFP91 | c.1452G>A p.T484= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as rs150478754, COSV60157029; called by muse, mutect2, varscan2
- ZNF691 | c.792C>T p.F264= (on ENST00000372502; = p.F233= on NM_015911.3) | Silent (SNP) | VAF 30/60 reads (50%) | catalogued as COSV100996091; called by muse, mutect2, varscan2
